Somatic mutation profile of tumor specimen 0DNJB8 from CCDI case PBCAZM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sertoli cell tumor, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 4.0 years (1,447 days).
Specimen 0DNJB8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04dcb4cf-deb4-4e49-b920-6b8b118850de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNJA2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2e095c5-cc2c-48e0-a248-e048200a7a8b

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 228/526 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, varscan2
- TRPA1 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 461/1067 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770145910, COSV51563035; called by muse, varscan2
- DLGAP2 | c.1725C>A p.A575= | Silent (SNP) | VAF 296/682 reads (43%) | catalogued as COSV101422705; called by muse, varscan2
- NOTCH3 | c.2934C>T p.S978= | Silent (SNP) | VAF 154/292 reads (53%) | called by muse, varscan2
